Surgical pathology report (de-identified scan), TCGA case TCGA-27-1837, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-1837-01A (Primary Tumor).

1

Ref. Number

Gender

Birth date

Tumor site

Left frontal

Histological diagnosis

Glioblastoma multiforme

Source: NCI Genomic Data Commons file a9865560-eed8-4130-b2bc-a21403575288 (TCGA-27-1837.FAB9682A-0940-4815-8789-81799FF395F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).